Gene-level copy-number profile of tumor specimen TCGA-49-6767-01A from TCGA case TCGA-49-6767, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.8 years (17,108 days).
Specimen TCGA-49-6767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b36580ea-acfc-4121-b610-105157f3f15e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-6767-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80036dbe-dfc7-4283-b540-bd6798d0dac1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 794; copy number 2: 7,321; copy number 3: 11,204; copy number 4: 18,773; copy number 5: 14,892; copy number 6: 3,315; copy number 7: 431; copy number 8: 175; copy number 9: 1,787; copy number 10: 398; copy number 11: 184; copy number 13: 1; copy number 17: 2; copy number 19: 400; copy number 26: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-6767-01A-11D-1854-01): tumor purity 0.43, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–3): MIR31HG.
- chr9:21,480,839–31,506,615, 97 genes (broad region; genes not listed).
- chr9:35,962,195–36,014,623, 1 gene (within-gene range 0–3): OR2S1P.
- chr9:35,991,336–37,034,268, 20 genes (within-gene range 0–3): OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,785 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–152,813,108, 390 genes, copy number 9–10 (broad region; genes not listed).
- chr7:63,113,635–159,233,377, 1,931 genes, copy number 9–19 (broad region; genes not listed).
- chr8:39,584,489–40,402,010, 16 genes, copy number 13–26 (within-gene range 4–26): ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1.
- chr8:41,509,593–41,578,421, 1 gene, copy number 9 (within-gene range 7–9): AC009630.1.
- chr8:41,529,218–43,030,535, 42 genes, copy number 9 (within-gene range 6–9): GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA.
- chr11:54,591,480–56,320,639, 87 genes, copy number 9 (broad region; genes not listed).
- chr11:60,756,867–61,213,098, 22 genes, copy number 10: MS4A15, MS4A10, AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1, PGA3.
- chr11:67,119,263–69,926,813, 112 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr21:24,840,550–26,573,286, 37 genes, copy number 11: LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1.
- chr22:18,623,339–21,192,156, 147 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 794. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
